Somatic mutation profile of tumor specimen ALCH-B4IG-TTP1-A (aliquot ALCH-B4IG-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4IG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.1 years (19,399 days).
Specimen ALCH-B4IG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8df2af7a-030b-4059-9c18-5ec9a9a109b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4IG-NB1-A (Blood Derived Normal), aliquot ALCH-B4IG-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ff88ae7-42d1-482a-92bc-bbd8c66367c0

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Splice Region 2, In Frame Del 1, Intron 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 58/612 reads (9%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel
- ACTR2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.804); catalogued as rs1440834418, COSV53200285; called by muse, mutect2
- CNOT1 | c.5402A>G p.N1801S | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as rs767422192; called by muse, mutect2, varscan2
- KCNS3 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 23/554 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868657815, COSV58408348; called by muse, mutect2
- CIAPIN1 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GSC2 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HMGCL | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 36/603 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- KRT36 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 9/251 reads (4%) | called by muse, mutect2
- LRP1 | c.9451G>T p.V3151L | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.266); called by muse, mutect2
- MAST3 | c.2057A>T p.N686I | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- NEBL | c.2151T>G p.V717= | Splice Region (SNP) | VAF 52/535 reads (10%) | called by muse, mutect2, varscan2
- OR5T1 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.168); called by muse, mutect2
- RAG1 | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 56/615 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RARRES1 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 25/357 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2
- RPS2 | c.270A>G p.E90= | Splice Region (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- SPOCK2 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2
- ZNF462 | c.6284T>A p.I2095N | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2
- ARHGAP1 | c.579C>T p.S193= | Silent (SNP) | VAF 30/286 reads (10%) | catalogued as rs771331768; called by muse, mutect2, varscan2
- BMPER | c.33T>C p.A11= | Silent (SNP) | VAF 33/913 reads (4%) | called by muse, mutect2
- CD163 | c.2011T>C p.L671= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- CD38 | c.765G>A p.Q255= | Silent (SNP) | VAF 15/190 reads (8%) | called by muse, mutect2
- HSPG2 | c.8997T>G p.P2999= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- LILRA2 | c.1272C>A p.L424= | Silent (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- MBIP | c.49C>T p.L17= | Silent (SNP) | VAF 55/358 reads (15%) | called by muse, mutect2, varscan2
- SNPH | c.447C>T p.I149= | Silent (SNP) | VAF 70/557 reads (13%) | catalogued as rs761585417, COSV60589326; called by muse, mutect2, varscan2
- UBAP2L | c.1686A>G p.S562= | Silent (SNP) | VAF 34/417 reads (8%) | called by muse, mutect2
- AL353804.4 | chrX:73821163 A>G | 3'Flank (SNP) | VAF 77/477 reads (16%) | called by muse, mutect2, varscan2
- TMEM11 | c.62+3057G>T | Intron (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
